Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5176, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5176-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with left renal mass.

TCGA - BP - 5176

Specimens Submitted:

1: SP: Left kidney

DIAGNOSIS:

- 1) KIDNEY, LEFT, NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), NUCLEAR GRADE II/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 2.1 CM. ✓
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. ✓
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. ✓
- THERE IS FOCAL TUMOR NECROSIS AS WELL AS FAT NECROSIS IN PERINEPHRIC SOFT TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled, "Left kidney". It consists of a 415 gram, 15.0 x 9.0 x 6.0 cm nephrectomy with 5.0 x 0.4 cm segment of ureter and dilated proximal ureter (approximately 1.5 cm), and 1.0 cm segment of the renal vein. The specimen is bivalved to reveal a 2.1 x 1.6 x 1.2 cm tan-yellow partially cystic, friable mass in the superior pole of the kidney. The lesion is cortically based with no gross extension through the capsule. The perirenal fat is grossly adherent above the mass. The remaining cortex is 0.5 cm and uniform. A 0.5 cm lower pole cortical cyst is present. No other lesions are grossly identified. The renal pelvis is dilated. The capsule overlying the tumor is inked black. A 1.5 cm focus of firm, tan-yellow fat and fibrous tissue is present outside the capsule adjacent to the renal lesion. The adrenal gland is not present. A portion of the tumor is saved for TPS and photographs are also taken.

Summary of Sections:

M - vascular and ureteral margins

T - tumor

NL - normal

PEL - representative renal pelvis

UR - representative ureter

PNF - perinephric fat with firm area adjacent to tumor

PF - representative pelvic fat

Summary of Sections:

[page 2 of 2]
Part 1: SP: Left kidney

Block	Sect. Site	PCs
1	m	1
1	nl	1
1	pel	1
2	pf	2
2	pnf	2
4	t	4
1	ur	1

Source: NCI Genomic Data Commons file 0f6dd941-1e94-4483-a697-f27b68f4dc88 (TCGA-BP-5176.4A7D1717-AC08-4DB3-98CD-0E41CA6F712A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).